Somatic mutation profile of tumor specimen C3L-01102-01 (aliquot CPT0124070007) from CPTAC case C3L-01102, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.0 years (17,168 days).
Specimen C3L-01102-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a771219-4ae1-45be-ab75-38a708d3df35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01102-31 (Blood Derived Normal), aliquot CPT0124930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaba0925-d1b8-4489-95b1-09d1d1f2e36c

The open-access MAF lists 34 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Frame Shift Del 2, Intron 2, 3'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.407T>C p.F136S | Missense Mutation (SNP) | VAF 78/433 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs5030833, CM941376, CM941377, COSV56542337, COSV56553831, COSV56565181; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CADPS | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51869514; called by muse, mutect2, varscan2
- LCOR | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 86/613 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63633051; called by muse, mutect2, varscan2
- MRPS18B | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 59/381 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as rs1389003067; called by muse, mutect2, varscan2
- MUC16 | c.16576T>A p.S5526T | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.334); catalogued as rs1287533336; called by muse, mutect2, varscan2
- OTUD7A | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs200755213, COSV61044267; called by muse, mutect2, varscan2
- PEPD | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 72/517 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs371934154; called by muse, mutect2, varscan2
- ALKBH8 | c.1168_1189del p.R390Lfs*5 | Frame Shift Del (DEL) | VAF 58/682 reads (9%) | called by mutect2, pindel
- AMIGO2 | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- B3GNT9 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- EFHC1 | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 58/402 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- IGHV1-18 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 15/468 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2
- KRBA1 | c.1177_1178del p.G393Hfs*26 | Frame Shift Del (DEL) | VAF 36/191 reads (19%) | called by pindel, varscan2
- KRBA1 | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAD1L1 | c.1893G>T p.K631N | Missense Mutation (SNP) | VAF 73/445 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- MARF1 | c.1736T>A p.I579N | Missense Mutation (SNP) | VAF 69/347 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- MEX3D | c.876G>T p.K292N | Missense Mutation (SNP) | VAF 86/488 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO3A | c.-17-1G>A | Splice Site (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- RO60 | c.1151G>T p.R384I | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SOBP | c.1933G>A p.V645M | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- TMEM106A | c.133T>A p.C45S | Missense Mutation (SNP) | VAF 78/531 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TRAPPC11 | c.2067dup p.A690Cfs*5 | Frame Shift Ins (INS) | VAF 14/150 reads (9%) | called by mutect2, pindel
- AASS | c.2577G>T p.V859= | Silent (SNP) | VAF 77/451 reads (17%) | called by muse, mutect2, varscan2
- DHPS | c.855G>A p.V285= | Silent (SNP) | VAF 48/350 reads (14%) | called by muse, mutect2, varscan2
- LAMA5 | c.8457C>T p.S2819= | Silent (SNP) | VAF 28/226 reads (12%) | catalogued as rs1048180546; called by muse, mutect2, varscan2
- MAP3K4 | c.963A>C p.S321= | Silent (SNP) | VAF 29/238 reads (12%) | called by muse, mutect2, varscan2
- PCDH8 | c.2664G>A p.E888= | Silent (SNP) | VAF 79/472 reads (17%) | catalogued as rs1566264173; called by muse, mutect2, varscan2
- PLSCR2 | c.495A>G p.R165= (on ENST00000497985 / NM_001199978.1; = p.R92= on NM_020359.2) | Silent (SNP) | VAF 66/348 reads (19%) | catalogued as COSV60862378; called by muse, mutect2, varscan2
- SDC4 | c.6C>T p.A2= | Silent (SNP) | VAF 43/251 reads (17%) | catalogued as rs1253202922; called by muse, mutect2, varscan2
- STARD9 | c.4227A>C p.A1409= | Silent (SNP) | VAF 47/238 reads (20%) | catalogued as rs759658377; called by muse, mutect2, varscan2
- TNIP1 | c.684G>A p.K228= | Silent (SNP) | VAF 82/363 reads (23%) | catalogued as rs1264726867; called by muse, mutect2, varscan2
- CSNK1D | c.886-614C>T | Intron (SNP) | VAF 23/112 reads (21%) | catalogued as rs775231197; called by muse, mutect2, varscan2
- LCN2 | c.275+36G>A | Intron (SNP) | VAF 46/518 reads (9%) | called by muse, mutect2
- TMCO1 | c.*209A>C | 3'UTR (SNP) | VAF 38/146 reads (26%) | called by muse, mutect2, varscan2
